Somatic mutation profile of tumor specimen TCGA-QH-A6CW-01A (aliquot TCGA-QH-A6CW-01A-11D-A32B-08) from TCGA case TCGA-QH-A6CW, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 43.4 years (15,847 days).
Specimen TCGA-QH-A6CW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cce827c-f572-4f2d-933a-ef50794f4314.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A6CW-10B (Blood Derived Normal), aliquot TCGA-QH-A6CW-10B-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38ebb957-cae8-46cf-ac12-f2cc2f31d5a4

The open-access MAF lists 40 somatic variants for this specimen: 34 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 22, In Frame Del 6, Silent 6, Frame Shift Del 4, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NOTCH1 | c.1070_1072del p.F357del | In Frame Del (DEL) | VAF 7/30 reads (23%) | hotspot (GDC flag); called by mutect2, varscan2
- SMARCA4 | c.2343G>A p.M781I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60787487, COSV60798909, COSV60801851; called by muse, mutect2
- TP53 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 32/38 reads (84%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AMOT | c.1675G>C p.A559P (on ENST00000371959 / NM_001113490.1; = p.A150P on NM_133265.3) | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV100494643; called by muse, mutect2
- BBX | c.1213C>G p.H405D | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.462); catalogued as COSV100360710; called by muse, mutect2
- CDH16 | c.1586T>G p.V529G | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100233553, COSV100233842; called by muse, mutect2, varscan2
- COL6A5 | c.7306C>T p.Q2436* (on ENST00000312481; = p.Q2432* on NM_153264.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99591398; called by muse, mutect2, varscan2
- DENND2C | c.2431+2T>A p.X811_splice (on ENST00000393274 / NM_001256404.2; = p.X754_splice on NM_198459.4) | Splice Site (SNP) | VAF 5/69 reads (7%) | catalogued as COSV101283871; called by muse, mutect2
- FCN1 | c.767_769del p.F256del | In Frame Del (DEL) | VAF 27/242 reads (11%) | catalogued as rs1241189260; called by pindel, varscan2
- FYB2 | c.1164del p.K388Nfs*6 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | catalogued as rs764585689; called by mutect2, pindel, varscan2
- GNAI3 | c.661A>G p.I221V | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.187); catalogued as rs1256508029, COSV100879795; called by muse, mutect2
- HEPH | c.3308A>G p.K1103R (on ENST00000343002; = p.K836R on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs200608069, COSV100293746; called by muse, mutect2, varscan2
- HGD | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs758291793, COSV52197800; called by muse, mutect2, varscan2
- IGSF3 | c.2431A>G p.K811E (on ENST00000369486 / NM_001007237.3; = p.K831E on NM_001542.4) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100603972; called by mutect2, varscan2
- KCNB2 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 117/276 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs971570323, COSV73051935; called by muse, mutect2, varscan2
- LGALS8 | c.759_762del p.R254Ifs*15 (on ENST00000341872; = p.R296Ifs*15 on NM_006499.4) | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | catalogued as rs1558168153; called by mutect2, varscan2
- LPAR3 | c.185A>C p.H62P | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101004631; called by muse, mutect2, varscan2
- MYH7 | c.2252T>C p.I751T | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV100805526; called by muse, mutect2, varscan2
- PHF8 | c.3116T>C p.L1039P (on ENST00000357988 / NM_001184896.1; = p.L1003P on NM_015107.3) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100153653; called by muse, mutect2, varscan2
- PHLPP1 | c.4027G>A p.G1343S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99406977; called by muse, mutect2, varscan2
- PPEF2 | c.1500C>G p.N500K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV99713962; called by muse, mutect2, varscan2
- PRKD2 | c.2282T>C p.I761T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99353977; called by muse, mutect2, varscan2
- PRPF4B | c.1279T>G p.S427A | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100527870; called by muse, mutect2, varscan2
- SBF1 | c.2324A>G p.K775R | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.991); catalogued as rs556408484, COSV100817343; called by muse, mutect2, varscan2
- SGO2 | c.2666A>G p.Y889C | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs774773159, COSV100764566; called by muse, mutect2, varscan2
- YWHAB | c.626A>G p.N209S | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.003); catalogued as COSV99407379; called by muse, mutect2, varscan2
- ZNF831 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64039507; called by muse, mutect2, varscan2
- ABCA13 | c.5547_5549del p.S1850del | In Frame Del (DEL) | VAF 10/28 reads (36%) | called by pindel, varscan2
- ATN1 | c.1176_1178del p.S395del | In Frame Del (DEL) | VAF 8/70 reads (11%) | called by pindel, varscan2
- CENPE | c.1403_1404del p.E468Vfs*2 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by pindel, varscan2
- GNAI2 | c.771_773del p.N257del | In Frame Del (DEL) | VAF 11/83 reads (13%) | called by pindel, varscan2
- NOTCH1 | c.6161_6162del p.K2054Rfs*213 | Frame Shift Del (DEL) | VAF 22/178 reads (12%) | called by mutect2, pindel, varscan2
- ZNF197 | c.496_543del p.C166_P181del | In Frame Del (DEL) | VAF 18/62 reads (29%) | called by mutect2, pindel
- CTAGE15 | c.66T>A p.V22= | Silent (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- HSD17B3 | c.585C>T p.Y195= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as rs762207020, COSV100931225; called by muse, mutect2, varscan2
- MECOM | c.2445G>A p.G815= (on ENST00000468789 / NM_001105078.4; = p.G1003= on NM_004991.4) | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99243642; called by muse, mutect2
- OR8D2 | c.12A>C p.S4= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100658839; called by muse, mutect2
- TICRR | c.4401C>T p.L1467= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV99175971; called by muse, mutect2, varscan2
- ZNF180 | c.657A>G p.K219= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV99659508; called by muse, mutect2, varscan2
